Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4761, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4761-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Patient with 14 cm right renal mass.

Specimens Submitted:

- 1: SP: Aortocaval nodes (1)
- 2: SP: Right kidney, adrenal and liver
- 3: SP: Retrocaval lymph node
- 4: SP: Gallbladder

DIAGNOSIS:

- 1) LYMPH NODES, AORTOCAVAL; EXCISION:
- THIRTEEN BENIGN LYMPH NODES (0/13).
- 2) KIDNEY, ADRENAL GLAND, AND LIVER, RIGHT; RADICAL NEPHRECTOMY, ADRENALECTOMY AND PARTIAL HEPATECTOMY:
- RENAL CELL CARCINOMA, (CONVENTIONAL) CLEAR CELL TYPE, NUCLEAR GRADE IV/IV.
- THE TUMOR GREATEST DIAMETER IS 12.0 CM.
- TUMOR EXTENDS THROUGH THE RENAL CAPSULE, INTO THE RENAL PELVIS, RENAL SINUS AND INTO LYMPHATICS AND VASCULAR SPACES. THERE ARE ADHESIONS BETWEEN TUMOR AND LIVER PARENCHYMA BUT THE LIVER PARENCHYMA IS UNINVOLVED BY TUMOR.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOMERULOSCLEROSIS, AND CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS NOT INVOLVED BY TUMOR.
- 3) LYMPH NODES, RETROCAVAL; EXCISION:
- TWO OUT OF THREE LYMPH NODES WITH METASTATIC RENAL CELL CARCINOMA (2/3).
- 4) GALLBLADDER; CHOLECYSTECTOMY:
- BENIGN GALLBLADDER.

1). The specimen is received in formalin labeled, "Aortocaval nodes". The specimen consists of multiple firm pink tan fleshy fatty lymph nodes ranging in size from 0.3 up to 1.5 cm in greatest dimension.

Summary of sections:

FSC -- frozen section control.

[page 2 of 3]
U -- remaining tissue.

2) The specimen is received fresh, labeled "Right kidney, adrenal and liver". It consists of a 1,160 gm, 17.0 x 12.0 x 8.0 cm radical nephrectomy with attached 8.0 x 6.0 x 2.0 cm portion of liver, 5.0 x 3.0 x 2.0 cm adrenal gland, and 5.0 x 0.5 cm segment of ureter. TPS and photographs are taken. The specimen is bisected to reveal a 12.0 x 10.0 x 8.0 cm variegated, gray-white to red mass with foci of hemorrhage and necrosis. A 6.0 x 4.0 x 2.0 cm portion of kidney remains uninvolved. The tumor is circumscribed with a capsule ranging from 0.5 to 1.0 cm in thickness. It is adherent to but not infiltrating the attached segment of liver parenchyma. A 3.0 x 2.5 x 2.5 cm polypoid mass is present within the renal attached end, present within the renal pelvis. Representative sections of that are submitted. The cut surface of the tumor displays a majority of gray-white fleshy area with attached adjacent hemorrhagic cystic, more yellow area. The renal vein is grossly uninvolved.

Summary of Sections:

M - vascular and ureteral margin

ADR - adrenal

TL - tumor to liver

HTA - hemorrhagic tumor area

GWTA - gray white firm tumor area

TN - tumor normal

TP - tumor to pelvis

NK - normal kidney

P - representative renal pelvis

PF - pelvic fat

3). The specimen is received fresh for frozen section labeled, "Retrocaval Nodes". The specimen consists of three firm pink tan fleshy fatty lymph nodes ranging from 0.5 by 1.0 cm in greatest dimension. Noted within the largest lymph node is a 0.5 cm necrotic nodule. Represented sectioning submitted.

Summary of sections:

FSCA -- frozen section control.

FSC b -- frozen section control

FSCC -- frozen section control.

4). The specimen is received in formalin labeled, "Gallbladder", and consists of a club-shaped gallbladder measuring 9 x 2 x 1 cm. The serosal surface is smooth. The cystic duct is identified and measures 0.5 cm in length and 0.4 cm in diameter, and on opening is grossly free of stones. On opening the gallbladder, is filled with dark green viscid bile and multiple black, multifaceted stones measuring 3 x 3 x 0.5 cm in aggregate. The mucosal surface is dark green and velvety and shows a few speckles of cholesterosis. The wall of the gallbladder is uniform in thickness measuring 0.2 cm. Representative section is submitted.

Summary of sections:

U-undesigned

Summary of Sections:

Part 1: SP: Aortocaval nodes

Block	Sect. Site	PCs
1	fsc	10
3	u	10

Part 2: SP: Right kidney, adrenal and liver (f)

Block	Sect. Site	PCs
1	adr	1
4	gwta	4
4	hta	4
1	m	1
1	nk	1
2	p	2

[page 3 of 3]
4	pf	4
3	tl	3
3	tn	3
4	tp	4

Part 3: SP: Retrocaval lymph node

Block	Sect. Site	PCs
1	fsca	1
1	fsch	10
1	fsc	10

Part 4: SP: Gallbladder (am)

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: CARCINOMA MODERATELY DIFFERENTIATED, METASTATIC TO A LYMPH NODE, MORPHOLOGICALLY COMPATIBLE WITH RENAL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 57286d5b-5db5-4c84-987d-04251c1ceab1 (TCGA-BP-4761.223BFE66-B95B-46BD-B192-D1D11542DEB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).